Somatic mutation profile of tumor specimen MP2PRT-PARVKR-TMP1-A (aliquot MP2PRT-PARVKR-TMP1-A-1-0-D-A79Q-36) from MP2PRT case MP2PRT-PARVKR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,308 days).
Specimen MP2PRT-PARVKR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8f609af-f8ad-486e-a48b-77dfbd8561f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARVKR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARVKR-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/428d11c0-e278-4536-bfa2-ee7520d03202

The open-access MAF lists 45 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 10, Nonsense Mutation 2, Frame Shift Del 1, 3'Flank 1, 5'Flank 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 39/254 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARID1B | c.5002G>A p.E1668K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1308269596, COSV51651369; called by muse, mutect2, varscan2
- CEP126 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.462); catalogued as COSV99681546; called by muse, mutect2, varscan2
- CSNK2A2 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1374223667, COSV52642966; called by muse, mutect2
- FSTL4 | c.2023G>A p.D675N | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1475770280; called by muse, mutect2
- GTSE1 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 28/462 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.745); catalogued as rs775482708, COSV71888926; called by muse, mutect2
- KCNA3 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as rs781637999; called by muse, mutect2, varscan2
- KDM5C | c.4669C>T p.Q1557* | Nonsense Mutation (SNP) | VAF 24/106 reads (23%) | catalogued as COSV64762506; called by muse, mutect2, varscan2
- LIMCH1 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 15/301 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs887529098; called by muse, mutect2
- NAV2 | c.1144C>T p.R382C (on ENST00000396087 / NM_001244963.2; = p.R359C on NM_145117.5) | Missense Mutation (SNP) | VAF 30/451 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs372267018; called by muse, mutect2
- SGSM3 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 109/284 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs778197171; called by muse, mutect2, varscan2
- TARBP2 | c.1043G>A p.R348H (on ENST00000266987 / NM_134323.2; = p.R327H on NM_004178.4) | Missense Mutation (SNP) | VAF 111/294 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs771785979, COSV99908609; called by muse, mutect2, varscan2
- VWA1 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as rs975223091; called by muse, mutect2, varscan2
- ZC3H7B | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); catalogued as COSV60960257; called by muse, mutect2, varscan2
- COPA | c.3515C>T p.S1172L | Missense Mutation (SNP) | VAF 24/369 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2
- CSN1S1 | c.244-1G>A p.X82_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- DENND4B | c.2624C>T p.A875V | Missense Mutation (SNP) | VAF 124/311 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.113); called by muse, varscan2
- DST | c.20648T>C p.I6883T (on ENST00000361203 / NM_001374722.1; = p.I4580T on NM_015548.5) | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- FAM241A | c.94G>C p.G32R | Missense Mutation (SNP) | VAF 45/512 reads (9%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.013); called by muse, mutect2
- FAM43B | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 53/460 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- FBXO24 | c.580G>C p.D194H (on ENST00000241071 / NM_033506.3; = p.D232H on NM_012172.5) | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IGHM | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- IGKV1-8 | c.345del p.P115del | Frame Shift Del (DEL) | VAF 27/45 reads (60%) | called by pindel*, varscan2
- KDM4E | c.1229C>G p.S410C | Missense Mutation (SNP) | VAF 48/352 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- MED12L | c.4617G>A p.W1539* | Nonsense Mutation (SNP) | VAF 36/231 reads (16%) | called by muse, mutect2, varscan2
- OGDH | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PIK3CB | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRM | c.3740T>C p.L1247P | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- RNF44 | c.1222G>C p.D408H | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM22 | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 37/283 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WDR36 | c.1406C>G p.S469C | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- ZBTB12 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 143/450 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY7 | c.1815C>G p.V605= | Silent (SNP) | VAF 49/357 reads (14%) | called by muse, mutect2, varscan2
- APEH | c.2040C>T p.F680= | Silent (SNP) | VAF 12/309 reads (4%) | called by muse, mutect2
- ASXL3 | c.5853T>C p.S1951= | Silent (SNP) | VAF 42/294 reads (14%) | called by muse, mutect2, varscan2
- CDS1 | c.333G>A p.L111= | Silent (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2, varscan2
- GAGE1 | c.210G>A p.P70= | Silent (SNP) | VAF 19/156 reads (12%) | called by muse, mutect2, varscan2
- KRTAP13-2 | c.282G>A p.T94= | Silent (SNP) | VAF 108/389 reads (28%) | catalogued as rs1486045736, COSV67762032; called by muse, mutect2, varscan2
- LRP1B | c.6933C>T p.V2311= | Silent (SNP) | VAF 31/209 reads (15%) | catalogued as COSV101253764; called by muse, mutect2, varscan2
- SIM1 | c.129C>T p.I43= | Silent (SNP) | VAF 30/274 reads (11%) | called by muse, mutect2, varscan2
- TMEM177 | c.762G>C p.L254= | Silent (SNP) | VAF 14/376 reads (4%) | called by muse, mutect2
- ZYX | c.1338C>T p.T446= | Silent (SNP) | VAF 82/281 reads (29%) | catalogued as COSV51974372; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915732 C>T | 5'Flank (SNP) | VAF 38/360 reads (11%) | called by muse, mutect2, varscan2
- HPS1 | c.937+22G>T | Intron (SNP) | VAF 20/216 reads (9%) | catalogued as rs1477066111; called by muse, mutect2
- IGKV2D-30 | chr2:89937680 del CC | 3'Flank (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel*
